Somatic mutation profile of tumor specimen TCGA-P4-A5E6-01A (aliquot TCGA-P4-A5E6-01A-11D-A28G-10) from TCGA case TCGA-P4-A5E6, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 67.4 years (24,615 days).
Specimen TCGA-P4-A5E6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 223afb07-f0a1-43b0-88f2-669971bcd605.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P4-A5E6-11A (Solid Tissue Normal), aliquot TCGA-P4-A5E6-11A-22D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9778f06-ed78-40ce-b776-ee046a0a50e6

The open-access MAF lists 87 somatic variants for this specimen: 72 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 14, Frame Shift Del 5, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 1, In Frame Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC008676.3 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 41/132 reads (31%) | catalogued as COSV56636578; called by muse, mutect2, varscan2
- AGO2 | c.1619T>C p.L540P | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55047141; called by muse, mutect2, varscan2
- ARHGAP21 | c.5476G>A p.G1826R | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs370251256, COSV57603623; called by muse, mutect2, varscan2
- ARRDC3 | c.1016T>G p.L339R | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54365074; called by muse, mutect2, varscan2
- ATG2A | c.483G>T p.E161D | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.967); catalogued as COSV65966664; called by muse, mutect2, varscan2
- ATP13A1 | c.2981A>G p.N994S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV52285418; called by muse, mutect2, varscan2
- BARX2 | c.728T>A p.L243H | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.319); catalogued as COSV55650245; called by muse, mutect2, varscan2
- BHLHE40 | c.832A>C p.I278L | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV56575508; called by muse, mutect2, varscan2
- CASP8AP2 | c.5023G>C p.V1675L | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV52746778; called by muse, mutect2, varscan2
- CENPF | c.1867A>T p.K623* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV65274765; called by muse, mutect2, varscan2
- COL14A1 | c.4967C>T p.P1656L | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52853659; called by muse, mutect2, varscan2
- CRNN | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760670901, COSV55121839; called by muse, mutect2, varscan2
- CSTF2T | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564612037, COSV58656392; called by muse, mutect2, varscan2
- DAG1 | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58184208; called by muse, mutect2, varscan2
- DBNDD1 | c.241A>T p.T81S (on ENST00000002501 / NM_001042610.3; = p.T101S on NM_024043.3) | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50022055; called by muse, mutect2, varscan2
- DNAJC16 | c.96A>C p.R32S | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV61601414; called by muse, mutect2, varscan2
- EGFL7 | c.492G>C p.W164C | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.649); catalogued as COSV58247550; called by muse, mutect2, varscan2
- EPRS1 | c.3491C>G p.T1164S | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65098698; called by muse, mutect2, varscan2
- ERCC6 | c.2744G>A p.R915Q | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs753804966, COSV63389882; called by muse, mutect2, varscan2
- FLNC | c.6574G>C p.E2192Q | Missense Mutation (SNP) | VAF 95/255 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.198); catalogued as COSV57955401; called by muse, mutect2, varscan2
- FOLR2 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53351540, COSV53351739; called by muse, varscan2
- FZD7 | c.972C>G p.Y324* | Nonsense Mutation (SNP) | VAF 63/203 reads (31%) | catalogued as COSV53809314; called by muse, mutect2, varscan2
- GABRB2 | c.370A>T p.N124Y | Missense Mutation (SNP) | VAF 103/234 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50909880; called by muse, mutect2, varscan2
- GNB1 | c.851T>G p.L284R | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66100535; called by muse, mutect2, varscan2
- GPR65 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs762323389, COSV50862678; called by muse, mutect2
- GRAMD1A | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761616229, COSV58766869; called by muse, mutect2, varscan2
- HDGF | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs375226201; called by muse, mutect2, varscan2
- INTS3 | c.1661A>T p.H554L | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.038); catalogued as COSV59677435; called by muse, mutect2, varscan2
- IPO9 | c.2675A>C p.D892A | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV64233609; called by muse, mutect2, varscan2
- ITGAD | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1317670905, COSV66757880; called by muse, mutect2, varscan2
- KAT2A | c.1363C>G p.P455A | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV56790646; called by muse, mutect2, varscan2
- KAT7 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.083); catalogued as COSV52014310; called by muse, mutect2, varscan2
- KIAA0100 | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV55931737; called by muse, mutect2, varscan2
- KLHL11 | c.748A>G p.R250G | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.367); catalogued as COSV59861946; called by muse, mutect2, varscan2
- LGALS3 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV54305031; called by muse, mutect2
- MECR | c.1018C>G p.L340V | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV55285276; called by muse, mutect2, varscan2
- MXD1 | c.634C>G p.Q212E | Missense Mutation (SNP) | VAF 22/331 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); catalogued as COSV52479707; called by muse, mutect2
- NAMPT | c.879A>C p.E293D | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV55994944; called by muse, mutect2
- NFE2L3 | c.1185G>T p.M395I | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV50227538, COSV50227738; called by muse, mutect2, varscan2
- PAM | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57212639; called by muse, mutect2
- PATJ | c.1624A>G p.M542V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.965); catalogued as COSV57161168; called by muse, mutect2, varscan2
- PCDHGB6 | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV53941755; called by muse, mutect2, varscan2
- PHKB | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54520411; called by muse, mutect2, varscan2
- PPP4R4 | c.2435T>A p.V812E | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as COSV58554313; called by muse, mutect2, varscan2
- PRICKLE4 | c.34G>A p.G12S (on ENST00000359201; = p.G52S on NM_013397.6) | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.631); catalogued as COSV59255041; called by muse, mutect2, varscan2
- RBL2 | c.2966G>A p.R989H | Missense Mutation (SNP) | VAF 67/263 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); catalogued as rs773997485, COSV50876911; called by muse, mutect2, varscan2
- RFX6 | c.526del p.L176Sfs*2 | Frame Shift Del (DEL) | VAF 32/81 reads (40%) | catalogued as COSV60589502; called by mutect2, pindel, varscan2
- RIPOR2 | c.1516G>C p.E506Q | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV52420975; called by muse, mutect2, varscan2
- RPE | c.436G>A p.G146R (on ENST00000359429 / NM_001318926.1; = p.G96R on NM_006916.2) | Missense Mutation (SNP) | VAF 111/145 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55991607; called by muse, mutect2, varscan2
- RRP7A | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV59899446; called by muse, mutect2, varscan2
- RSPH6A | c.1722G>C p.E574D | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.287); catalogued as COSV55571313; called by muse, mutect2, varscan2
- SBK2 | c.173T>G p.V58G | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV60014052; called by muse, mutect2
- SHMT2 | c.97C>G p.Q33E | Missense Mutation (SNP) | VAF 149/371 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100197455, COSV61073898; called by muse, mutect2, varscan2
- SLCO3A1 | c.805C>A p.L269M | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59229387, COSV59229453; called by muse, mutect2, varscan2
- SPINK1 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1213003, COSV57024803; called by muse, mutect2, varscan2
- STRIP2 | c.1759C>G p.L587V | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50804116; called by muse, mutect2, varscan2
- TEX10 | c.728G>C p.S243T | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV66515271; called by muse, mutect2, varscan2
- TPCN1 | c.1144A>C p.T382P | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV59235042; called by muse, mutect2, varscan2
- TRAF2 | c.270C>G p.A90= | Splice Region (SNP) | VAF 14/47 reads (30%) | catalogued as COSV56037694; called by muse, mutect2, varscan2
- TRPM6 | c.1056G>C p.Q352H | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1051664359, COSV62509288; called by muse, mutect2, varscan2
- TSBP1 | c.1136A>C p.K379T (on ENST00000617061; = p.K384T on NM_006781.5) | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV66658661; called by muse, mutect2, varscan2
- UBR4 | c.2908C>A p.L970M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV64388895; called by muse, mutect2, varscan2
- ZBTB46 | c.1440C>A p.S480R | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV55509733, COSV99829246; called by muse, mutect2, varscan2
- CCDC18 | c.2748_2764+17del p.X916_splice (on ENST00000343253 / NM_001306076.1; = p.X917_splice on NM_206886.4) | Splice Site (DEL) | VAF 22/144 reads (15%) | called by mutect2, pindel
- CEP83 | c.942dup p.L315Tfs*2 | Frame Shift Ins (INS) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- CUL3 | c.48_49delinsA p.M16Ifs*8 | Frame Shift Del (DEL) | VAF 82/170 reads (48%) | called by pindel, varscan2*
- GAREM1 | c.1395del p.Q466Sfs*7 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | called by mutect2, pindel, varscan2
- ITPKB | c.376_390del p.E126_K130del | In Frame Del (DEL) | VAF 26/79 reads (33%) | called by mutect2, pindel, varscan2
- MYH15 | c.2218dup p.R740Kfs*16 | Frame Shift Ins (INS) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- RBP3 | c.1960C>G p.P654A | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- TLR5 | c.1058del p.S353Ifs*10 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
- YOD1 | c.1003del p.E335Nfs*22 | Frame Shift Del (DEL) | VAF 36/131 reads (27%) | called by mutect2, pindel, varscan2
- BICRA | c.1560G>T p.L520= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV67604674; called by muse, mutect2, varscan2
- HLA-E | c.978T>C p.A326= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV64927486; called by muse, mutect2, varscan2
- KHDC4 | c.126G>C p.G42= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs147323254; called by muse, mutect2, varscan2
- MAPKAPK3 | c.1113C>G p.G371= | Silent (SNP) | VAF 103/240 reads (43%) | catalogued as COSV63597334; called by muse, mutect2, varscan2
- NOC3L | c.144A>G p.K48= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV64929873; called by muse, mutect2, varscan2
- OTUD7A | c.849C>T p.S283= (on ENST00000307050 / NM_001382637.1; = p.S276= on NM_130901.3) | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs758269775, COSV61038394; called by muse, mutect2, varscan2
- PRMT6 | c.405C>T p.V135= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1349478405, COSV63655474; called by muse, mutect2, varscan2
- PTPRF | c.4341C>T p.V1447= | Silent (SNP) | VAF 107/307 reads (35%) | catalogued as COSV63444741; called by muse, mutect2, varscan2
- RNLS | c.90T>G p.L30= | Silent (SNP) | VAF 56/163 reads (34%) | catalogued as COSV59293193; called by muse, mutect2
- TAS1R1 | c.468C>T p.A156= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs150596151; called by muse, mutect2, varscan2
- USP48 | c.936T>C p.N312= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV57609587; called by muse, mutect2, varscan2
- VIM | c.1326T>G p.L442= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs759925135, COSV56405690; called by muse, mutect2, varscan2
- WDR90 | c.2499C>T p.P833= | Silent (SNP) | VAF 90/278 reads (32%) | catalogued as rs763030348, COSV53469416; called by muse, mutect2
- ZFYVE26 | c.1584C>A p.L528= | Silent (SNP) | VAF 65/173 reads (38%) | catalogued as COSV61327917, COSV61328343; called by muse, mutect2, varscan2
- LINC02694 | n.33A>C | RNA (SNP) | VAF 43/145 reads (30%) | catalogued as COSV59558669; called by muse, mutect2, varscan2
